Gene-level copy-number profile of tumor specimen HCM-SANG-1085-C20-08A-01D-A80T-32 from HCMI case HCM-SANG-1085-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectum, NOS; Tumor grade: G3.
Specimen HCM-SANG-1085-C20-08A-01D-A80T-32: Sample type: Post neo-adjuvant therapy; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file bcc3cb2c-6d41-495c-969d-d4146a8baa7a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1085-C20-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/fa838b93-5142-4724-9682-c6815732a856

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 6; copy number 2: 1,196; copy number 3: 3,853; copy number 4: 18,083; copy number 5: 3,684; copy number 6: 26,873; copy number 7: 374; copy number 8: 4,396; copy number 10: 387; copy number 11: 21; copy number 12: 1; copy number 13: 1; copy number 14: 3; copy number 18: 17; copy number 19: 9.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,486,926–49,523,857, 4 genes: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2.
- chr4:49,588,772–49,589,529, 1 gene: SNX18P25.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 30 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:50,858,760–50,934,521, 3 genes, copy number 14: AC022441.1, AC022441.3, AC022441.2.
- chr10:90,402,521–92,030,325, 27 genes, copy number 13–19: LINC02653, AL391704.1, AL391704.2, HTR7, RPP30, Y_RNA, ANKRD1, RNU6-740P, AL365434.1, AL365434.2, LINC00502, DDX18P6, NUDT9P1, PCGF5, HECTD2, AL161798.1, RPS27P1, PPP1R3C, GAPDHP28, FAF2P1, TNKS2-AS1, TNKS2, SRP9P1, AL359198.2, FGFBP3, AL359198.1, BTAF1.

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
